Gene-level copy-number profile of tumor specimen TCGA-CA-5797-01A from TCGA case TCGA-CA-5797, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.6 years (20,662 days).
Specimen TCGA-CA-5797-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a4e164cc-f3d9-4bdf-a447-5c2cd54121fd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CA-5797-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f94d02dd-37d6-4283-a592-38212b9d6842

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 842; copy number 2: 29,993; copy number 3: 25,484; copy number 4: 344; copy number 5: 1,346; copy number 6: 1,558; copy number 7: 20; copy number 8: 206; copy number 24: 18; copy number 26: 2; copy number 31: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CA-5797-01A-01D-1649-01): tumor purity 0.64, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,528,861–60,033,020, 3 genes: NDUFB4P2, MIR582, AC034234.1.
- chr8:51,257,688–51,321,118, 1 gene: AC012413.1.
- chr8:51,435,602–51,436,509, 1 gene: BRIX1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,151 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–67,239,519, 1,270 genes, copy number 5–7 (broad region; genes not listed).
- chr8:35,672,195–35,707,734, 1 gene, copy number 31 (within-gene range 1–31): AC105230.1.
- chr8:41,929,479–42,737,407, 20 genes, copy number 24–26 (within-gene range 1–26): KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1.
- chr8:46,028,804–50,796,692, 75 genes, copy number 5 (broad region; genes not listed).
- chr8:51,015,021–51,015,165, 1 gene, copy number 7: AC090919.1.
- chr8:68,302,246–85,951,083, 268 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:90,001,405–93,850,075, 58 genes, copy number 5: DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 842. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
